Somatic mutation profile of tumor specimen TCGA-4N-A93T-01A (aliquot TCGA-4N-A93T-01A-11D-A36X-10) from TCGA case TCGA-4N-A93T, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 67.1 years (24,523 days).
Specimen TCGA-4N-A93T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16c90847-8fb1-44e2-bf8c-a045f81bfe03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4N-A93T-10A (Blood Derived Normal), aliquot TCGA-4N-A93T-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89dac5a6-1a2a-499c-8a81-c6b124e979d3

The open-access MAF lists 104 somatic variants for this specimen: 72 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 31, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 165/194 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 85/229 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.2521C>T p.R841* | Nonsense Mutation (SNP) | VAF 77/213 reads (36%) | catalogued as rs797045752, COSV56953286; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC26A2 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 55/157 reads (35%) | catalogued as rs1057517532, COSV99639919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 25/37 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.212A>G p.H71R | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV99266763; called by muse, mutect2, varscan2
- ACADL | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99284459; called by muse, mutect2, varscan2
- ALDH3A1 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 20/243 reads (8%) | catalogued as rs778654435, COSV99855688, COSV99855796; called by muse, mutect2
- ALS2CL | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs200208936, COSV100014623; called by muse, mutect2, varscan2
- ARHGAP22 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781379645, COSV50932764; called by muse, mutect2, varscan2
- ARHGAP5 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 61/116 reads (53%) | catalogued as COSV100564902; called by muse, mutect2, varscan2
- ARID5A | c.834G>C p.E278D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV62591141; called by muse, mutect2, varscan2
- ATP8B2 | c.1076C>T p.S359F (on ENST00000672630; = p.S326F on NM_001005855.2) | Missense Mutation (SNP) | VAF 110/290 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs772371760, COSV59246075; called by muse, mutect2, varscan2
- B3GALT4 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV101005532, COSV65851556; called by muse, mutect2, varscan2
- BAD | c.57G>C p.E19D | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV57402117; called by muse, mutect2, varscan2
- BCAS3 | c.1755C>A p.F585L (on ENST00000390652 / NM_001353144.2; = p.F570L on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101174791, COSV66772513; called by muse, mutect2, varscan2
- BRD4 | c.3985C>T p.R1329W | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99649657; called by muse, mutect2, varscan2
- CACNA1E | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 122/365 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV62405927, COSV62425336; called by muse, mutect2, varscan2
- CLEC4C | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV63583253; called by muse, mutect2, varscan2
- CNTNAP3 | c.2881C>T p.H961Y | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs1221177347, COSV99903846; called by muse, mutect2, varscan2
- COL5A1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs201375465, COSV65666869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPD | c.3483C>A p.H1161Q | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV99852309; called by muse, mutect2, varscan2
- DLEC1 | c.2102C>A p.S701Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100341112; called by muse, mutect2, varscan2
- DNAH17 | c.3092C>A p.T1031N | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV101101056; called by muse, mutect2, varscan2
- ELF3 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.197); catalogued as COSV100668573; called by muse, mutect2
- ENPP2 | c.427C>A p.H143N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.395); catalogued as COSV99307180; called by muse, mutect2
- FAM222A | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs776600173, COSV100734456; called by muse, mutect2, varscan2
- FAT3 | c.5474C>T p.T1825M | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs756801253, COSV53110476; called by muse, mutect2, varscan2
- FBN2 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52513181; called by muse, mutect2, varscan2
- FSCN3 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs141748303; called by muse, mutect2, varscan2
- GUCY1A2 | c.2095G>T p.V699L | Missense Mutation (SNP) | VAF 6/170 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56480549, COSV56503884; called by muse, mutect2
- HMCN1 | c.10220A>T p.D3407V | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99622319; called by muse, mutect2, varscan2
- IGHE | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 74/96 reads (77%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs782517271; called by muse, mutect2, varscan2
- JCAD | c.1520A>T p.D507V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV100947975; called by muse, mutect2, varscan2
- JCAD | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV100947978; called by muse, mutect2, varscan2
- KANK3 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs779611225, COSV58360148; called by muse, mutect2, varscan2
- KCNN2 | c.26G>A p.G9D (on ENST00000264773; = p.G221D on NM_021614.4) | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); catalogued as rs1452487427, COSV99298472; called by muse, mutect2
- KIAA0100 | c.6274C>T p.R2092C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756175527, COSV56382119; called by muse, mutect2, varscan2
- KIAA1549 | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99649369; called by muse, mutect2, varscan2
- MMP9 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490544892, COSV100812309; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2100G>T p.Q700H | Missense Mutation (SNP) | VAF 10/135 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV64055625; called by muse, mutect2
- MYO3A | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746307707, COSV56318875, COSV99780654; called by muse, mutect2, varscan2
- NARF | c.251A>C p.K84T | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV59111761; called by muse, mutect2, varscan2
- NDST4 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated (0.33); PolyPhen benign (0.042); catalogued as rs564044682, COSV52131759, COSV52141204, COSV99995081; called by muse, mutect2, varscan2
- NIPBL | c.375G>T p.Q125H | Missense Mutation (SNP) | VAF 165/435 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV99238201; called by muse, mutect2, varscan2
- NLRP3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100275042; called by muse, mutect2, varscan2
- OR5AN1 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.481); catalogued as COSV58322095; called by muse, mutect2, varscan2
- OSTF1 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV100653588; called by muse, mutect2, varscan2
- OXTR | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs769146293, COSV57479562; called by muse, mutect2, varscan2
- PCDHB5 | c.1484C>A p.P495Q | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.159); catalogued as COSV99167563; called by muse, mutect2, varscan2
- PLXNA2 | c.4240G>A p.D1414N | Missense Mutation (SNP) | VAF 51/92 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs748477176, COSV100884881; called by muse, mutect2, varscan2
- PRMT7 | c.1145T>C p.I382T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV100266552; called by muse, mutect2, varscan2
- PROK2 | c.370A>C p.I124L (on ENST00000295619 / NM_001126128.2; = p.I103L on NM_021935.4) | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV55208825; called by muse, mutect2, varscan2
- PRPF39 | c.1966A>T p.N656Y | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV99360697; called by muse, mutect2
- PXDN | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.514); catalogued as rs1023904208, COSV53239764; called by muse, mutect2, varscan2
- RASIP1 | c.2768G>A p.G923D | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.366); catalogued as COSV99710391; called by muse, mutect2, varscan2
- RBM25 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1401779697, COSV56198617; called by muse, mutect2
- SPEF2 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 56/132 reads (42%) | catalogued as rs758170951, COSV56797955; called by muse, mutect2, varscan2
- TCEAL5 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 32/367 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV65503429; called by muse, mutect2
- TEX13A | c.1105C>A p.Q369K | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.15); PolyPhen benign (0.118); catalogued as COSV100780598; called by muse, mutect2, varscan2
- TGM5 | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as rs768591773, COSV99588606; called by muse, mutect2, varscan2
- TOX3 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV99566882; called by muse, mutect2, varscan2
- USF3 | c.4669C>A p.P1557T | Missense Mutation (SNP) | VAF 116/330 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100324582; called by muse, mutect2, varscan2
- WAC | c.1875-2A>C p.X625_splice | Splice Site (SNP) | VAF 112/289 reads (39%) | catalogued as COSV100610822, COSV100610900; called by muse, mutect2, varscan2
- ZFHX4 | c.940A>G p.S314G | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99254355; called by muse, mutect2, varscan2
- ZNF33A | c.1169G>T p.G390V (on ENST00000458705 / NM_006974.3; = p.G391V on NM_006954.2) | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV100275415, COSV100275944; called by muse, mutect2, varscan2
- ZNF668 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV56214533; called by muse, mutect2, varscan2
- GUCY1A2 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 6/170 reads (4%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); called by muse, mutect2
- KHSRP | c.659dup p.G221Rfs*37 | Frame Shift Ins (INS) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- PCNX2 | c.895del p.V299Yfs*10 | Frame Shift Del (DEL) | VAF 40/112 reads (36%) | called by mutect2, pindel, varscan2
- UHRF1BP1 | c.3643del p.L1215Cfs*6 | Frame Shift Del (DEL) | VAF 62/183 reads (34%) | called by mutect2, pindel, varscan2
- ZMYM4 | c.4591_4615delinsGA p.H1531Dfs*2 | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | called by pindel, varscan2*
- CAPN15 | c.582C>T p.H194= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs576084802, COSV99562078; called by muse, mutect2, varscan2
- CARD11 | c.2058C>T p.N686= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs1329394605, COSV62753956; called by muse, mutect2, varscan2
- CEP290 | c.2143T>C p.L715= | Silent (SNP) | VAF 26/506 reads (5%) | catalogued as COSV100467522; called by muse, mutect2
- CHST4 | c.312C>T p.C104= | Silent (SNP) | VAF 53/154 reads (34%) | catalogued as rs544697900, COSV58298234; called by muse, mutect2, varscan2
- CRLF1 | c.1080G>C p.S360= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs748177094, COSV62260699; called by muse, mutect2, varscan2
- CXCR6 | c.810C>A p.I270= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV99945021; called by muse, mutect2, varscan2
- DDI1 | c.1053C>T p.I351= | Silent (SNP) | VAF 93/185 reads (50%) | catalogued as rs1226735014, COSV56368599, COSV56374872; called by muse, mutect2, varscan2
- DMRT1 | c.885G>A p.P295= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as rs771988103, COSV101206605; called by muse, mutect2, varscan2
- DSC2 | c.810A>G p.K270= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV99199433; called by muse, mutect2
- DTX4 | c.471C>T p.L157= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs749542653, COSV57088608; called by muse, mutect2, varscan2
- EPPK1 | c.4368C>T p.P1456= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs375180416, COSV73261274; called by muse, mutect2, varscan2
- FFAR3 | c.117C>T p.F39= | Silent (SNP) | VAF 134/706 reads (19%) | catalogued as rs148149328, COSV100588087; called by muse, mutect2, varscan2
- GFM2 | c.1347A>G p.S449= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as COSV57190843; called by muse, mutect2, varscan2
- GPRIN2 | c.1128G>A p.P376= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs111800394, COSV65401248, COSV65401530; called by muse, mutect2, varscan2
- JCAD | c.1149C>T p.S383= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs757793496, COSV64759406; called by muse, mutect2, varscan2
- MAN2A1 | c.2037A>G p.S679= | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as COSV99810255; called by muse, mutect2, varscan2
- ME3 | c.1014C>T p.G338= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs757380399, COSV62774557, COSV62775919; called by muse, mutect2, varscan2
- N4BP3 | c.889C>T p.L297= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99200592; called by muse, mutect2, varscan2
- NUTF2 | c.327C>T p.N109= | Silent (SNP) | VAF 115/263 reads (44%) | catalogued as rs567238959, COSV99534145; called by muse, mutect2, varscan2
- OLIG2 | c.408G>A p.P136= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs529308616, COSV100324159; called by muse, mutect2, varscan2
- OR6B3 | c.102C>T p.T34= | Silent (SNP) | VAF 48/82 reads (59%) | catalogued as COSV100096747; called by muse, mutect2, varscan2
- OR8S1 | c.1056C>T p.R352= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV59599608; called by muse, mutect2, varscan2
- PKD1L2 | c.471C>G p.G157= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100450508, COSV61415289; called by muse, mutect2
- PTDSS2 | c.409C>T p.L137= | Silent (SNP) | VAF 146/341 reads (43%) | catalogued as COSV100338996; called by muse, mutect2, varscan2
- RBFOX1 | c.117G>A p.A39= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs771957716, COSV60951047; called by muse, mutect2
- SFMBT2 | c.429G>A p.P143= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1323772461, COSV62810138, COSV62811516; called by muse, mutect2, varscan2
- SLC1A6 | c.465C>T p.P155= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as rs760995484, COSV55674010; called by muse, mutect2, varscan2
- SLC2A13 | c.1614T>G p.L538= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as COSV55111501, COSV99785645; called by muse, mutect2, varscan2
- SVIL | c.3090C>T p.D1030= (on ENST00000355867 / NM_021738.3; = p.D604= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as COSV100880742; called by muse, mutect2, varscan2
- TMPRSS15 | c.1731C>T p.N577= | Silent (SNP) | VAF 162/403 reads (40%) | catalogued as rs1199394405, COSV99516422; called by muse, mutect2, varscan2
- TNS1 | c.3162C>T p.A1054= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs1221430825, COSV99409586; called by muse, mutect2, varscan2
- LIM2 | c.175+29C>T | Intron (SNP) | VAF 29/88 reads (33%) | catalogued as rs533314455, COSV99702174; called by muse, mutect2, varscan2
